Somatic mutation profile of tumor specimen TCGA-DU-7306-01A (aliquot TCGA-DU-7306-01A-11D-2086-08) from TCGA case TCGA-DU-7306, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 67.9 years (24,800 days).
Specimen TCGA-DU-7306-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b3d0eea-32da-4e96-a3a7-b0d60fff01e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7306-10A (Blood Derived Normal), aliquot TCGA-DU-7306-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fe469f9-170e-4934-8014-74053411c43b

The open-access MAF lists 59 somatic variants for this specimen: 47 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.2696G>A p.G899E | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555399094, COSV57319878; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 38/110 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 52/129 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.1957G>C p.A653P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV59749180; called by muse, mutect2, varscan2
- ADARB2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV67214616; called by muse, mutect2, varscan2
- AKAP6 | c.5336T>G p.I1779S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV55217336; called by muse, mutect2, varscan2
- ANAPC7 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 133/331 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV71443862; called by muse, mutect2, varscan2
- ANKRD6 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs200509240, COSV60232614; called by muse, mutect2, varscan2
- ASB4 | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV57945870; called by muse, mutect2, varscan2
- ATAD2 | c.1982C>G p.T661S | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54881985; called by muse, mutect2, varscan2
- CATSPERE | c.2444T>C p.I815T | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as rs1187945478, COSV63678738; called by muse, mutect2, varscan2
- CCNE2 | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57376430; called by muse, mutect2
- CETN1 | c.449A>C p.D150A | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59121564; called by muse, mutect2, varscan2
- CHD7 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV71111930; called by muse, mutect2, varscan2
- CRYBG1 | c.5987T>C p.I1996T | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV64812688; called by muse, mutect2
- CSF2RA | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62625125; called by muse, mutect2, varscan2
- CXCR4 | c.1028A>G p.E343G | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as COSV54013376; called by muse, mutect2, varscan2
- FAM83B | c.2939A>G p.N980S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV60923105; called by muse, mutect2
- FOCAD | c.2107-1G>A p.X703_splice | Splice Site (SNP) | VAF 16/71 reads (23%) | catalogued as COSV58101285; called by muse, mutect2, varscan2
- GJA8 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV53789223; called by muse, mutect2, varscan2
- GOLGB1 | c.8365G>A p.A2789T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs770543826, COSV61463196; called by muse, mutect2, varscan2
- GRWD1 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53519149; called by muse, mutect2, varscan2
- IL1R1 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.214); catalogued as COSV52106531; called by muse, mutect2
- LAMC2 | c.2146G>C p.V716L | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV51456567; called by muse, mutect2, varscan2
- LPCAT3 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV54646156; called by muse, mutect2, varscan2
- LRRC8D | c.2500C>G p.L834V | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV61579728; called by muse, mutect2, varscan2
- MEX3C | c.1426G>C p.G476R | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV68530098; called by muse, mutect2, varscan2
- NAV1 | c.394G>C p.A132P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55219263; called by muse, mutect2, varscan2
- NLRP13 | c.1988T>A p.L663H | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61622362; called by muse, mutect2
- OR2Z1 | c.605C>A p.S202* | Nonsense Mutation (SNP) | VAF 23/187 reads (12%) | catalogued as COSV60692672; called by muse, mutect2, varscan2
- OR4C11 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100155592, COSV56353774; called by muse, mutect2, varscan2
- PAFAH1B1 | c.640A>G p.K214E | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV68210320; called by muse, mutect2, varscan2
- PLPPR4 | c.223-1G>C p.X75_splice | Splice Site (SNP) | VAF 8/140 reads (6%) | catalogued as COSV64569781; called by muse, mutect2
- RAD54L2 | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.168); catalogued as COSV56579270; called by muse, mutect2, varscan2
- RIC1 | c.3380C>A p.A1127D | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV52610654; called by muse, mutect2, varscan2
- RNF14 | c.151A>G p.S51G | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as COSV61662507; called by muse, mutect2
- SEC24B | c.2521C>G p.L841V | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54501203; called by muse, mutect2
- SLC9B2 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.172); catalogued as COSV60019895; called by muse, mutect2, varscan2
- STAG3 | c.3665T>C p.I1222T | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs761260270, COSV57931450; called by muse, mutect2, varscan2
- TBC1D31 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV54867264; called by mutect2, varscan2
- TIGD2 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57648057; called by muse, mutect2, varscan2
- TRIM58 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs368652011, COSV63569097; called by muse, mutect2, varscan2
- UGT1A5 | c.499A>T p.I167F | Missense Mutation (SNP) | VAF 10/299 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV59390919; called by muse, mutect2
- ZNF492 | c.1374del p.F458Lfs*12 | Frame Shift Del (DEL) | VAF 70/128 reads (55%) | catalogued as COSV71762204; called by mutect2, pindel, varscan2
- ATRX | c.6338_6341del p.F2113Sfs*9 | Frame Shift Del (DEL) | VAF 26/38 reads (68%) | called by pindel, varscan2
- NIPBL | c.2843dup p.R949Qfs*17 | Frame Shift Ins (INS) | VAF 53/163 reads (33%) | called by mutect2, pindel, varscan2
- ZNF462 | c.4766del p.L1589Wfs*4 | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- ABCF1 | c.2397C>G p.A799= (on ENST00000326195 / NM_001025091.2; = p.A761= on NM_001090.3) | Silent (SNP) | VAF 19/618 reads (3%) | catalogued as rs1481945831, COSV58229448; called by muse, mutect2
- ABHD10 | c.486A>C p.A162= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV56325372; called by muse, mutect2, varscan2
- CXorf58 | c.907T>C p.L303= | Silent (SNP) | VAF 61/80 reads (76%) | catalogued as COSV64858390; called by muse, mutect2, varscan2
- DNAJC7 | c.1314C>T p.L438= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV57269293; called by muse, mutect2, varscan2
- KIAA1328 | c.87C>T p.Y29= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs562943084, COSV54456163; called by muse, mutect2, varscan2
- MFN2 | c.2235C>T p.L745= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as COSV52423009; called by muse, mutect2, varscan2
- MYB | c.1593A>G p.E531= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV57198571; called by muse, mutect2
- RXRA | c.189G>A p.P63= | Silent (SNP) | VAF 100/242 reads (41%) | catalogued as rs764586715, COSV62684499; called by muse, mutect2, varscan2
- VWA1 | c.798G>A p.T266= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV58600051; called by muse, mutect2, varscan2
- ZDHHC23 | c.1206C>T p.I402= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs567969212, COSV57629668; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1175G>A | Intron (SNP) | VAF 15/53 reads (28%) | catalogued as rs757844138, COSV63752762; called by muse, mutect2, varscan2
- POLR1D | c.*1T>C | 3'UTR (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100265949; called by muse, mutect2, varscan2
